Somatic mutation profile of tumor specimen TCGA-25-2409-01A (aliquot TCGA-25-2409-01A-01W-0799-08) from TCGA case TCGA-25-2409, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-25-2409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfd4a7cb-1e80-4bee-892d-33f0f97b752e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2409-10A (Blood Derived Normal), aliquot TCGA-25-2409-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9df7f8e-748a-4971-9db9-7b812c8c883e

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 232/573 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs199473175, CM024643, COSV100347038; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 166/254 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1222469299, COSV65449560; called by muse, mutect2, varscan2
- ATRX | c.4211C>T p.T1404I | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100971187; called by muse, mutect2
- CEP72 | c.1323C>G p.H441Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1346889814; called by muse, mutect2
- CLCN7 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs765414475, COSV99247503; called by muse, varscan2
- DEPTOR | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53813745; called by muse, mutect2, varscan2
- DNAJA3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs758995316, COSV52161236; called by muse, mutect2, varscan2
- ENG | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554810243, COSV61226717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HABP4 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV64514674; called by muse, mutect2, varscan2
- IQCA1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs370868790; called by muse, mutect2, varscan2
- LRFN5 | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247533; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1409806572, COSV53797057; called by muse, mutect2, varscan2
- MYH7 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1232358310, CM1411007, COSV62516516; called by muse, mutect2, varscan2
- OR4N2 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 310/828 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60050526; called by muse, varscan2
- PCCA | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs368047060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGD | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54620638, COSV54621320; called by muse, mutect2
- S1PR3 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs754837512, COSV63980310; called by muse, mutect2, varscan2
- SGO2 | c.2569C>G p.Q857E | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63414438; called by muse, mutect2, varscan2
- SH3D19 | c.2170A>C p.S724R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV58789652; called by muse, mutect2, varscan2
- THBS2 | c.52+1G>A p.X18_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV64677623; called by muse, mutect2, varscan2
- VPS13B | c.10916A>G p.Y3639C | Missense Mutation (SNP) | VAF 113/198 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215467176, COSV62136312; called by muse, mutect2, varscan2
- APOB | c.12315_12339del p.R4105Sfs*16 | Frame Shift Del (DEL) | VAF 165/501 reads (33%) | called by mutect2, pindel, varscan2
- SI | c.2336_2371del p.D779_L791delinsV | In Frame Del (DEL) | VAF 32/246 reads (13%) | called by mutect2, pindel
- ARHGEF18 | c.585C>T p.Y195= (on ENST00000359920 / NM_001130955.2; = p.Y91= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs143912880; called by muse, mutect2, varscan2
- GIMAP1 | c.525C>T p.R175= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV56187952; called by muse, mutect2, varscan2
- KRI1 | c.768G>A p.E256= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1275075462; called by muse, mutect2
- MBD6 | c.1044C>G p.A348= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as rs1057396696, COSV63073546; called by muse, mutect2, varscan2
- OR1L1 | c.399G>A p.V133= (on ENST00000373686; = p.V83= on NM_001005236.3) | Silent (SNP) | VAF 448/1214 reads (37%) | catalogued as COSV58935370; called by muse, mutect2, varscan2
- PCM1 | c.5604T>C p.P1868= | Silent (SNP) | VAF 126/153 reads (82%) | catalogued as COSV59585764; called by muse, mutect2, varscan2
- PCMTD2 | c.564C>T p.V188= | Silent (SNP) | VAF 12/284 reads (4%) | catalogued as COSV55059281; called by muse, mutect2
- PTCD3 | c.729C>T p.N243= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs75290041, COSV54479084; called by muse, mutect2, varscan2
- TPO | c.1371C>T p.I457= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100221731, COSV61097344; called by muse, mutect2, varscan2
- ZNF324B | c.204C>T p.T68= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as rs755318433, COSV60740941; called by muse, mutect2, varscan2
